Gene-level copy-number profile of specimen HCM-CSHL-0182-C25-85A from HCMI case HCM-CSHL-0182-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.6 years (27,264 days).
Specimen HCM-CSHL-0182-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4fa6337e-2fdc-40dc-ae9a-3c8b82cbf46a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0182-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/b2f0aa77-5fe2-4029-a236-4ad374dd75a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 11; copy number 2: 2,326; copy number 3: 880; copy number 4: 33,047; copy number 5: 3,421; copy number 6: 13,390; copy number 7: 2,273; copy number 8: 1,852; copy number 9: 162; copy number 10: 1,277; copy number 13: 114; copy number 15: 2; copy number 17: 1; copy number 18: 13; copy number 20: 12; copy number 21: 1; copy number 38: 120.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,702 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,494,853–53,794,904, 263 genes, copy number 13–38 (within-gene range 6–38) (broad region; genes not listed).
- chr6:63,521,746–63,616,361, 6 genes, copy number 9: PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18.
- chr13:19,674,752–114,337,626, 1,279 genes, copy number 9–10 (within-gene range 4–10) (broad region; genes not listed).
- chr18:12,288,308–12,658,134, 9 genes, copy number 9 (within-gene range 7–9): AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1.
- chr20:20,970,448–26,251,546, 144 genes, copy number 9 (broad region; genes not listed).
- chr22:18,533,646–18,577,968, 1 gene, copy number 9: PI4KAP1.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
